Somatic mutation profile of tumor specimen TCGA-XM-A8RC-01A (aliquot TCGA-XM-A8RC-01A-11D-A423-09) from TCGA case TCGA-XM-A8RC, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type B2, malignant; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 67.5 years (24,660 days).
Specimen TCGA-XM-A8RC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ce1c695-f8d5-4ebc-bb65-65ca89eaf261.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XM-A8RC-10A (Blood Derived Normal), aliquot TCGA-XM-A8RC-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f93bdfcb-2091-4cdb-9559-5be99f428332

The open-access MAF lists 24 somatic variants for this specimen: 16 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 7, Frame Shift Del 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSL1 | c.2027C>T p.A676V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs759188602, COSV55660753; called by mutect2, varscan2
- CMSS1 | c.464C>T p.S155L | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs746747839, COSV70435767; called by muse, mutect2, varscan2
- DMBT1 | c.3284C>T p.S1095F (on ENST00000338354 / NM_001377530.1; = p.S596F on NM_004406.3) | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.223); catalogued as rs766342819; called by muse, mutect2
- RNF213 | c.8000C>G p.S2667C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV60392181; called by muse, mutect2
- SOBP | c.1753del p.R585Gfs*22 | Frame Shift Del (DEL) | VAF 4/37 reads (11%) | catalogued as rs1554190709, COSV58003572; called by mutect2, pindel
- TBC1D2B | c.1094T>G p.V365G | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV56042032; called by muse, mutect2
- TDO2 | c.401C>T p.T134M | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765002500; called by muse, mutect2
- BCOR | c.1099T>A p.S367T | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2
- CFAP47 | c.481A>G p.K161E | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.388); called by muse, mutect2
- CLTC | c.460A>T p.I154F | Missense Mutation (SNP) | VAF 7/141 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- EPS15 | c.491T>C p.I164T | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); called by muse, mutect2
- HPS4 | c.1969G>A p.A657T | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNQ5 | c.1514G>A p.C505Y | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- LDHC | c.249del p.Y83* | Frame Shift Del (DEL) | VAF 7/75 reads (9%) | called by mutect2, pindel
- NCOA2 | c.2393A>C p.Q798P | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- TSN | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.92); PolyPhen benign (0.011); called by muse, mutect2
- DCLRE1A | c.1617T>G p.P539= | Silent (SNP) | VAF 6/51 reads (12%) | called by mutect2, varscan2
- FASTKD5 | c.1518T>G p.T506= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV53909481, COSV99417879; called by muse, mutect2
- FLNC | c.1245G>A p.V415= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as rs1333370324; called by muse, mutect2, varscan2
- RAB27A | c.174G>T p.P58= | Silent (SNP) | VAF 8/40 reads (20%) | called by muse, mutect2, varscan2
- TASOR | c.4359A>G p.E1453= (on ENST00000355628 / NM_001365636.2; = p.E1077= on NM_015224.3) | Silent (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2, varscan2
- TRAK2 | c.60T>C p.N20= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as rs1187341084; called by muse, mutect2, varscan2
- TUBB6 | c.87C>T p.G29= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as rs376972319, COSV58353987; called by muse, mutect2, varscan2
- AK9 | c.3633+13_3633+15del | Intron (DEL) | VAF 5/42 reads (12%) | catalogued as rs201441562; called by pindel, varscan2
